Surgical pathology report (de-identified scan), TCGA case TCGA-29-1766, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1766-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1766

Surg Path

CLINICAL HISTORY:

Abnormal pelvic swelling.

GROSS EXAMINATION:

A. "Omentum (A1)", received fresh. A 20 x 18 x 8 cm portion of firm, matted yellow-fibrofatty tissue with an embedded unoriented 15 cm length of bowel upon sectioning. The bowel mucosa is velvety-tan and grossly unremarkable. The firm fat has a solid white-tan cut surface with areas of cystic formation. There are also area of soft white friable material (A1 Frozen section; remnant in A1, additional blocks A2-5 demonstrating bowel wall and papillations).

B. "Left tube and ovary", received fresh. A 26.5 gm, aggregate of tissue composed of a 3.7 x 0.5 cm segment of fallopian tube adjacent to a 2.9 x 1.8 x 1.5 cm ovary with abundant attached fibrofatty tissue. The ovarian surface is slightly erythematous and focally granular but with no nodules or masses identified. Sectioning reveals a grossly unremarkable cut surface. The majority of the ovary is submitted as B1-2 in addition to sections of fallopian tube.

C. "Right tube and ovary", received fresh. A 26.6 gm, aggregate of tissue composed of a 5.5 x 1 cm segment of fallopian tube focally adherent upon a 2.7 x 1.8 x 1.4 cm ovary with slightly erythematous and focally granular surface. The fallopian tube lumen is focally distended near the fimbriated end and contains blood clots and soft friable material. Sectioning through the ovary reveals a grossly unremarkable cut surface. Representative from the dilated segment of fallopian tube submitted as C1 and from the ovary as C2.

D. "Uterus and cervix", received fresh. A 103.2 gm, 8.5 x 5.8 x 2.8 cm uterus is received. The serosa is smooth, red-tan. The ectocervix is white-pink and glistening with a central patent 3 cm os extending into a trabecular yellow endocervical canal with a 1.2 cm polyp on the posterior wall (D2). The endometrium is velvety-tan, 0.1 cm in thickness overlying a 1.2 cm myometrium containing an ill-defined cystic whorled nodularity most prominent in the fundus (D5).

BLOCK SUMMARY:

- D1- anterior cervix
- D2- posterior cervix polyp
- D3- anterior endomyometrium
- D4- posterior endomyometrium
- D5- fundic nodularity

E. "Small bowel mesentery", received fresh. A 2.7 x 1.7 x 0.6 cm fragment of firm, nodular yellow-tan fibrofatty tissue is sectioned and entirely submitted as E1.

F. "Segment of small bowel", received fresh. An unoriented 14 cm length of small bowel with an average diameter of 2.5 cm is received with attached indurated and focally hemorrhagic fat. The mesentery is received stapled and there is a nodular firm, 13 x 5 x 1 cm area of firm, friable tumor mass abutting the small bowel wall. The small bowel mucosa is velvety-tan grossly unremarkable with no lesions identified. Representative sections of the small bowel in relationship to mesenteric tumor mass submitted as F1-2.

INTRA OPERATIVE CONSULTATION:

[page 2 of 2]
A. "Omentum": Afl- papillary carcinoma [REDACTED] [REDACTED]

TCGA-29-1766

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY & BILATERAL SALPINGO-OOPHORECTOMY, OMENTECTOMY,
PARTIAL SMALL BOWEL RESECTION

PATHOLOGIC STAGE (AJCC 6th Edition):

pT3c pNX pM1 (if either ovary or fallopian tube primary)

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] Registry as required for accreditation by the [REDACTED]. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

UNCERTAIN PRIMARY LOCATION

C. "RIGHT OVARY":

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 2

TUMOR SIZE: LARGELY SURFACE, 1.0 CM IN AREA, PENETRATE < 1 MM INTO WALL

SEROSA: TUMOR IS PRESENT

C. "RIGHT FALLOPIAN":

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 2

TUMOR SIZE: LUMEN FILLED WITH TUMOR 1.1 CM IN DIAMETER

SPECIMENS WITH METASTATIC/IMPLANTED TUMOR

A. OMENTUM

A. SMALL BOWEL WALL WITH CLOSE EXTENSION TO MUCOSA

B. MINUTE FOCUS ON SURFACE OF LEFT OVARY

E. SMALL BOWEL MESENTERY

F. SMALL BOWEL WALL WITH CLOSE EXTENSION TO MUCOSA

SPECIMENS FREE OF TUMOR

D. UTERUS, 103.2 GRAMS

ENDOMETRIUM: ATROPHIC

MYOMETRIUM: ADENOMYOSIS;

LEIOMYOMAS UP TO 5 MM IN MAXIMUM DIAMETER

CERVIX: NO PATHOLOGIC DIAGNOSIS.

SEROSA: NO TUMOR PRESENT

NOTE: The location of the primary source is uncertain. Most of the tumor is peritoneal. A major focus is in the fallopian tube. The surface of the ovary is the least likely, but by the definition set by the [REDACTED] this is a distinct possibility.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by: [REDACTED]

Source: NCI Genomic Data Commons file c8608413-4232-4c8e-b2de-3bd84c517846 (TCGA-29-1766.FC0A444E-3618-459A-A3EE-58EC9E7E1084.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).